Somatic mutation profile of tumor specimen BA2375D (aliquot aq-BA2375D) from BEATAML1.0 case 2330, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 72.8 years (26,585 days).
Specimen BA2375D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b25f05e-dd40-4c55-813e-a6ff2b6e6f70.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2729D (Solid Tissue Normal), aliquot aq-BA2729D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc5b8cb0-54a5-4cb4-8d38-d1c064d33c27

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BMP7 | c.1276C>T p.R426W | Missense Mutation (SNP) | VAF 18/464 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1252706270, COSV101216440; called by muse, mutect2
- CASC3 | c.2074C>A p.P692T | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MRC2 | c.701A>G p.D234G | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.046); called by muse, mutect2
- MYL10 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RIT1 | c.153T>A p.D51E | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SVEP1 | c.6751T>C p.W2251R | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
